Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A769, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A769-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Melanoma, nodular
8721/3

Site Skin gels
CC44.7

pn 8/22/13

Operative Procedure:

Excision of right calf lesion

Pre-Operative Diagnosis:

Right calf mass

Specimen Received:

Right calf mass

Final Pathologic Diagnosis:

Right calf mass:

Malignant melanoma, see below

Procedure	Excision
Site	Calf
Laterality	Right
Type	Nodular, polypoid
Thickness	7.4 cm
Level	Clark's level IV
Ulceration	Present
Mitosis/mm2	10/mm2
Microsatellitosis	Present
Lymphovascular invasion	Present
Regression	None identified
Perineural invasion	None identified
Tumor infiltrating lymphocytes	Non-brisk
Satellite nodule (gross finding)	Present
Margin status	Margins free
Excisions, distance from margin	2mm to peripheral margin
Precursor lesion	None identified

pT4b, Nx, Mx

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received in formalin, labeled "right calf mass" is a 15.3 x 8.3 cm tan, wrinkled skin ellipse excised to a depth of 2.8 cm. There is a central 12.2 x 11.1 x 7.4 cm tan-gray to brown nodular, fungating well delineated mass, which comes to within 2.4 cm from the nearest skin margin. This mass on sectioning is tan to red, firm, heterogeneous, focally hemorrhagic and partially necrotic (5%), coming to within 2.9 cm from the inked deep margin. Located 1.2 cm from this mass is a 6.1 x 3.4 x 2.5 cm tan to red, irregular, well delineated, multinodular satellite lesion, which comes to within 0.3 cm

[page 2 of 2]
from the nearest inked skin margin. This mass on sectioning is tan-gray to red, firm, heterogeneous, well delineated, partially necrotic (5%), coming to within 1.1 cm from the inked deep soft tissue margin. No other lesions are identified on sectioning.

Representative sections are submitted as follows:

- 1 tips;
- 2 inked deep margin taken perpendicular;
- 3-8 larger mass;
- 9 satellite lesion to nearest inked skin margin;
- 10 satellite mass to inked deep soft tissue margin.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age:) Gender: M

HIFAA Discrepancy		☒

Source: NCI Genomic Data Commons file de12055c-d1c3-4727-b33c-855ed2945ecf (TCGA-GF-A769.BE27D542-F31E-4F76-86B3-6BDEF790C31B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).